Gene-level copy-number profile of tumor specimen ALCH-ACHI-TTP1-A from ALCHEMIST case ALCH-ACHI, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 64.7 years (23,619 days).
Specimen ALCH-ACHI-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 53e876fe-7cee-4ab8-bfc9-de9d8d1080f1.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ACHI-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,720 have no estimate.
https://portal.gdc.cancer.gov/files/642e5157-26b3-40f9-ad5f-53556b5efa41

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 181; copy number 1: 6,798; copy number 2: 51,782; copy number 3: 102; copy number 4: 19; copy number 5: 14; copy number 6: 2; copy number 7: 3; copy number 9: 2.

Homozygous deletions (total copy number 0; autosomes only): 181 genes in 44 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:127,048,027–127,107,288, 1 gene: BIN1.
- chr2:127,625,997–127,626,848, 1 gene (within-gene range 0–2): AC010976.2.
- chr2:131,821,987–131,836,532, 3 genes: AC103564.3, AC103564.1, AC103564.2.
- chr2:238,100,340–238,152,947, 2 genes (within-gene range 0–1): ESPNL, KLHL30.
- chr7:63,699,390–63,771,047, 2 genes: AC079355.1, CICP24.
- chr7:66,511,556–66,592,397, 2 genes (within-gene range 0–2): AC008267.3, AC006001.3.
- chr7:151,012,209–151,144,436, 11 genes (within-gene range 0–2): ATG9B, ABCB8, AC010973.1, ASIC3, CDK5, SLC4A2, AC010973.3, AC010973.2, FASTK, TMUB1, AGAP3.
- chr8:22,114,419–22,141,951, 2 genes: HR, REEP4.
- chr8:141,340,505–141,367,286, 3 genes: LINC01300, AC100803.3, GPR20.
- chr9:134,317,098–134,440,585, 2 genes: RXRA, MIR4669.
- chr11:63,974,620–64,166,113, 8 genes (within-gene range 0–1): COX8A, AP000721.1, OTUB1, MACROD1, AP000721.2, AP006333.2, FLRT1, AP006333.1.
- chr11:67,991,100–68,004,982, 1 gene: UNC93B1.
- chr11:77,128,246–77,215,241, 1 gene: MYO7A.
- chr14:19,324,708–19,700,650, 22 genes: AL929602.1, LINC01297, GRAMD4P3, POTEG, AL512624.2, RNU6-1268P, MED15P6, NF1P4, AL512310.11, AL512624.1, NF1P11, AL512310.3, AL512310.10, AL512310.8, AL512310.4, AL512310.5, AL512310.6, AL512310.9, AL512310.7, AL512310.2, ARHGAP42P4, AL512310.1.
- chr15:25,170,723–25,225,284, 30 genes (within-gene range 0–2): SNORD115-1, SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30.
- chr15:41,837,775–41,894,053, 4 genes (within-gene range 0–2): PLA2G4B, SPTBN5, RNA5SP393, MIR4310.
- chr15:75,647,912–75,727,688, 5 genes (within-gene range 0–2): SNX33, CSPG4, AC105020.4, AC105020.1, ODF3L1.
- chr16:67,148,104–67,272,191, 17 genes (within-gene range 0–2): B3GNT9, TRADD, FBXL8, AC074143.1, HSF4, NOL3, KIAA0895L, EXOC3L1, E2F4, ELMO3, MIR328, AC040160.2, LRRC29, TMEM208, FHOD1, SLC9A5, AC040160.1.
- chr16:68,367,325–68,370,262, 1 gene (within-gene range 0–2): AC099521.2.
- chr16:87,830,023–87,869,507, 3 genes: SLC7A5, MIR6775, AC126696.2.
- chr16:88,382,959–88,537,031, 4 genes (within-gene range 0–2): ZNF469, ZFPM1, MIR5189, AC116552.1.
- chr17:18,225,635–18,268,828, 4 genes: LLGL1, FLII, MIEF2, AC127537.1.
- chr17:18,950,345–19,022,595, 4 genes (within-gene range 0–2): SLC5A10, AC090286.1, FAM83G, AC090286.4.
- chr17:29,573,475–29,614,761, 3 genes (within-gene range 0–2): GIT1, ANKRD13B, AC104564.4.
- chr17:63,695,888–63,702,670, 2 genes (within-gene range 0–2): LIMD2, AC046185.3.
- chr18:79,395,856–79,529,325, 6 genes (within-gene range 0–1): NFATC1, AC018445.3, AC018445.5, AC018445.1, AC018445.4, AC018445.2.
- chr19:301,444–344,815, 2 genes (within-gene range 0–3): MIER2, AC016588.1.
- chr19:2,714,567–2,740,048, 5 genes: DIRAS1, AC006538.2, AC006538.4, AC006538.1, SLC39A3.
- chr19:19,512,418–19,537,581, 4 genes: TSSK6, NDUFA13, AC011448.1, YJEFN3.
- chr19:38,738,284–38,739,863, 1 gene (within-gene range 0–2): AC022144.1.
- chr19:55,312,029–55,334,048, 2 genes (within-gene range 0–2): AC020922.2, TMEM150B.
- chr20:3,227,417–3,239,559, 1 gene: SLC4A11.
- chr21:36,698,773–36,701,564, 1 gene (within-gene range 0–2): AP000697.1.
- chr21:44,300,051–44,327,376, 1 gene: PFKL.
- chr22:18,936,411–18,959,512, 2 genes (within-gene range 0–7): AC007326.5, AC007326.2.
- chr22:19,018,043–19,018,916, 1 gene (within-gene range 0–1): AC000095.1.
- chr22:19,031,564–19,034,564, 1 gene: CA15P1.
- chr22:19,045,256–19,061,843, 4 genes (within-gene range 0–2): Y_RNA, DGCR11, AC004461.1, AC004461.2.
- chr22:29,705,256–29,767,011, 5 genes: AC004882.1, AC004882.2, CABP7, ZMAT5, Y_RNA.
- chr22:45,875,999–46,010,777, 3 genes (within-gene range 0–2): BX324167.1, WNT7B, BX537318.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 21 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:18,333,726–18,419,273, 4 genes, copy number 5: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr21:10,612,455–13,067,033, 6 genes, copy number 5: SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P.
- chr21:43,053,191–43,168,646, 4 genes, copy number 5–9 (within-gene range 1–9): CBS, U2AF1, AP001631.2, MRPL51P2.
- chr21:43,159,066–43,162,277, 1 gene, copy number 5: AP001631.1.
- chr22:18,733,914–18,757,906, 1 gene, copy number 9: FAM230E.
- chr22:18,873,543–18,947,732, 5 genes, copy number 6–7 (within-gene range 0–7): FAM230F, AC008103.1, DGCR6, AC007326.4, PRODH.

Autosomal genes at a single copy (total copy number 1): 3,993. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
